Somatic mutation profile of tumor specimen TCGA-AR-A0TQ-01A (aliquot TCGA-AR-A0TQ-01A-11D-A099-09) from TCGA case TCGA-AR-A0TQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 27.0 years (9,873 days).
Specimen TCGA-AR-A0TQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0921da06-00d8-4451-9f5f-7472261080ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TQ-10A (Blood Derived Normal), aliquot TCGA-AR-A0TQ-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63057d8c-4cb5-46fb-92a1-1ea844947225

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL6 | c.1160G>A p.R387H (on ENST00000379240; = p.R412H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs571229269, COSV99732835; called by muse, mutect2, varscan2
- ADD1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370911124; called by muse, mutect2, varscan2
- ATP9A | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 48/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100125698; called by muse, varscan2
- BRIP1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51994263, COSV52009007; called by muse, mutect2
- CDADC1 | c.1124A>C p.Y375S | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99212617; called by muse, mutect2, varscan2
- DDR2 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100906904; called by muse, mutect2, varscan2
- DNAH11 | c.12769G>T p.D4257Y | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100181140; called by muse, mutect2
- DNAH8 | c.1653C>G p.I551M | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100547324; called by muse, mutect2, varscan2
- FCRL5 | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100709388; called by muse, mutect2, varscan2
- GATA3 | c.989_990insC p.R330Sfs*22 | Frame Shift Ins (INS) | VAF 31/159 reads (19%) | catalogued as COSV100651279, COSV60521988; called by mutect2, pindel, varscan2
- GCM2 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371918069; ClinVar: uncertain significance; called by muse, mutect2
- GIMAP5 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs927435790, COSV57530170; called by muse, mutect2, varscan2
- NCOA3 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV100508343; called by muse, mutect2, varscan2
- NPHS1 | c.2819G>T p.R940L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV100800301; called by muse, mutect2
- NRAP | c.4627A>T p.R1543W (on ENST00000359988 / NM_001322945.2; = p.R1508W on NM_006175.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63489458; called by muse, mutect2
- PIK3R1 | c.1390G>A p.D464N (on ENST00000521381 / NM_181523.3; = p.D194N on NM_181504.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57131926, COSV57141496, COSV99144900; called by muse, mutect2, varscan2
- PLCE1 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564843295, COSV53346498, COSV99597461; called by muse, mutect2, varscan2
- RIMS1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as COSV99330879; called by muse, mutect2, varscan2
- TBC1D22B | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs150909093; called by muse, mutect2, varscan2
- TIMD4 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745745551, COSV50861557; called by muse, mutect2, varscan2
- TJP1 | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as rs761548583, COSV100633226; called by muse, mutect2, varscan2
- TXNDC11 | c.2597G>A p.R866Q (on ENST00000356957 / NM_001303447.2; = p.R839Q on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs747981331, COSV51598664; called by muse, mutect2, varscan2
- ZKSCAN2 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as rs775594356, COSV100048597; called by muse, mutect2, varscan2
- CAPS | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2
- ARIH1 | c.336C>T p.H112= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs986868497, COSV101158918; called by muse, mutect2
- BAK1 | c.57G>A p.L19= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100645894; called by muse, mutect2
- CDH22 | c.273C>T p.D91= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs149912052; called by muse, mutect2
- CHRM2 | c.1032G>T p.V344= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs1476228739, COSV100282058; called by muse, mutect2, varscan2
- CXorf58 | c.951G>A p.T317= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as rs775722910; called by muse, mutect2, varscan2
- DLG5 | c.1947G>A p.P649= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs550335548, COSV100967932, COSV64948466; called by muse, mutect2, varscan2
- EPS15L1 | c.1149G>A p.V383= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV50171542; called by muse, mutect2, varscan2
- MS4A6E | c.75G>A p.E25= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as COSV100279240, COSV55728255; called by muse, mutect2, varscan2
- NRAP | c.4626T>C p.S1542= (on ENST00000359988 / NM_001322945.2; = p.S1507= on NM_006175.4) | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100668112; called by muse, mutect2
- SCN10A | c.4230G>T p.L1410= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV101479551; called by muse, mutect2, varscan2
- SERPINE1 | c.1155C>T p.V385= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99776856; called by muse, mutect2, varscan2
- UNC45A | c.399G>T p.R133= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100376645; called by muse, mutect2, varscan2
- CAV1 | c.-2G>T | 5'UTR (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100592043; called by muse, mutect2, varscan2
- DUSP13 | c.*816G>A | 3'UTR (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100403884; called by muse, mutect2, varscan2
